Gene-level copy-number profile of tumor specimen TCGA-AX-A3FW-01A from TCGA case TCGA-AX-A3FW, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 66.9 years (24,419 days).
Specimen TCGA-AX-A3FW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.78af4999-6a03-4ac1-8130-0116eb32b5f3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AX-A3FW-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4caf74a6-b900-4306-9f27-843fc0bc9fa0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 5,653; copy number 2: 49,280; copy number 3: 4,565; copy number 4: 163; copy number 5: 72; copy number 6: 23; copy number 7: 53; copy number 8: 7.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AX-A3FW-01A-11D-A227-01): tumor purity 0.93, ploidy 2.01, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 155 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:180,509,380–180,566,523, 2 genes, copy number 6: OVAAL, Y_RNA.
- chr1:234,811,052–235,097,412, 8 genes, copy number 7–8 (within-gene range 3–8): AL391832.4, RNY4P16, RN7SL668P, AL391832.1, AL391832.2, AL391832.3, LINC01348, AL732292.1.
- chr2:15,801,747–16,204,226, 14 genes, copy number 7: AC113608.1, RNU5E-7P, RPLP1P5, AC010145.2, MYCNOS, MYCNUT, MYCN, RN7SL104P, AC010145.1, GACAT3, AC130710.1, AC174048.1, AC142283.1, AC010745.1.
- chr2:16,227,027–16,228,194, 1 gene, copy number 7: AC010745.3.
- chr3:66,622,760–66,824,439, 4 genes, copy number 6: AC104440.1, RPL21P41, AC098969.2, AC098969.1.
- chr3:168,858,659–169,038,416, 5 genes, copy number 6: RPL21P43, LINC02082, AC092954.1, AC092954.2, LINC01997.
- chr3:187,958,775–188,154,057, 5 genes, copy number 5 (within-gene range 3–5): LINC01991, AC092941.1, AC092941.2, AC022498.1, LPP-AS2.
- chr3:188,178,543–188,180,812, 1 gene, copy number 5: FLJ42393.
- chr4:89,879,532–89,999,409, 2 genes, copy number 5 (within-gene range 5–6): MMRN1, AC105445.1.
- chr10:112,149,865–112,215,377, 1 gene, copy number 7: GPAM.
- chr12:52,229,093–52,367,481, 14 genes, copy number 7: METTL7AP1, KRT7, KRT7-AS, KRT86, KRT87P, AC021066.2, AC021066.1, AC021066.3, KRT81, AC121757.2, AC121757.1, KRT83, KRT89P, KRT85.
- chr12:53,739,611–53,898,976, 1 gene, copy number 5 (within-gene range 3–5): AC076968.2.
- chr12:53,816,185–54,497,688, 51 genes, copy number 5 (within-gene range 2–5): RN7SKP289, HOXC13-AS, HOXC13, HOXC12, HOTAIR, AC012531.5, AC012531.7, AC012531.4, AC012531.6, HOXC11, HOXC-AS3, HOXC10, AC012531.3, HOXC6, MIR196A2, HOXC-AS2, HOXC9, HOXC-AS1, HOXC8, HOXC4, AC012531.2, AC012531.1, HOXC5, MIR615, FLJ12825, AC023794.3, AC023794.2, FAM242C, Y_RNA, SMUG1, LINC02381, AC023794.5, AC023794.4, AC023794.1, CBX5, MIR3198-2, RN7SL390P, SCAT2, AC078778.1, HNRNPA1, NFE2, COPZ1, RNU6-950P, MIR148B, RN7SL744P, AC079313.2, AC079313.1, GPR84, ZNF385A, ITGA5, LINC01154.
- chr12:55,997,180–56,237,846, 22 genes, copy number 7 (within-gene range 2–7): SUOX, IKZF4, AC034102.8, AC034102.3, RPS26, ERBB3, AC034102.2, PA2G4, AC034102.4, RPL41, ESYT1, ZC3H10, AC034102.7, AC034102.6, AC034102.5, MYL6B, MYL6, SMARCC2, AC073896.4, RNF41, NABP2, SLC39A5.
- chr14:68,113,706–68,236,539, 4 genes, copy number 5: AL133370.2, AL133370.1, RN7SL706P, RN7SL108P.
- chr17:75,498,548–75,757,818, 12 genes, copy number 6 (within-gene range 3–6): MIR6785, CASKIN2, TSEN54, LLGL2, MYO15B, RECQL5, SMIM5, SMIM6, SAP30BP, AC087749.2, AC087749.1, ITGB4.
- chr20:31,664,452–31,870,747, 8 genes, copy number 5 (within-gene range 2–5): BCL2L1, BCL2L1-AS1, ABALON, TPX2, AL160175.1, MYLK2, FOXS1, DUSP15.

Autosomal genes at a single copy (total copy number 1): 5,653. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
